Gene-level copy-number profile of tumor specimen TCGA-36-2539-01A from TCGA case TCGA-36-2539, project TCGA-OV (Ovarian Serous Cystadenocarcinoma).
Specimen TCGA-36-2539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e8242e31-e8eb-4cf6-81db-27f5be5294e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2539-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc855cb1-7732-4651-87b7-60d34ec0f410

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 19,372; copy number 2: 33,370; copy number 3: 6,178; copy number 4: 189; copy number 5: 621; copy number 6: 9; copy number 7: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-2539-01): tumor purity 0.58, ploidy 1.8, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,078,015–46,484,424, 8 genes (within-gene range 0–1): AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2.
- chr2:46,448,224–46,448,511, 1 gene: RN7SL817P.
- chr7:63,011,463–63,636,617, 39 genes: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 653 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:73,510,658–95,234,391, 469 genes, copy number 5 (broad region; genes not listed).
- chr11:102,295,060–112,086,798, 184 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
